Somatic mutation profile of tumor specimen TCGA-LN-A49Y-01A (aliquot TCGA-LN-A49Y-01A-11D-A27G-09) from TCGA case TCGA-LN-A49Y, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 77.0 years (28,125 days).
Specimen TCGA-LN-A49Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d90d2623-60ce-467a-8821-e20c8f1c78be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LN-A49Y-10A (Blood Derived Normal), aliquot TCGA-LN-A49Y-10A-01D-A27G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47467cbf-c032-4b6b-8eee-9ead239f5cf7

The open-access MAF lists 272 somatic variants for this specimen: 191 protein-altering or splice-affecting, 70 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 165, Silent 70, Nonsense Mutation 14, RNA 5, Splice Site 3, Frame Shift Del 2, In Frame Del 2, 3'Flank 2, Intron 2, Splice Region 2, Frame Shift Ins 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.824G>T p.C275F | Missense Mutation (SNP) | VAF 167/346 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 114/239 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRB3 | c.1227G>T p.W409C | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101000350; called by muse, mutect2, varscan2
- ADGRE3 | c.1810C>A p.Q604K | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as COSV53728105; called by muse, mutect2, varscan2
- AEBP1 | c.3054_3068del p.Q1020_Q1024del | In Frame Del (DEL) | VAF 10/48 reads (21%) | catalogued as rs755132794; called by mutect2, varscan2
- AEN | c.128G>T p.R43L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV60430621; called by muse, mutect2, varscan2
- ARHGAP5 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as rs78337553, COSV61533654; called by muse, mutect2
- ASMT | c.458G>T p.R153L | Missense Mutation (SNP) | VAF 64/75 reads (85%) | SIFT tolerated (0.85); PolyPhen benign (0.005); catalogued as COSV67109568; called by muse, mutect2, varscan2
- ATP1A3 | c.2446G>T p.G816C (on ENST00000545399 / NM_001256214.2; = p.G803C on NM_152296.5) | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.962); catalogued as COSV57491827; called by muse, mutect2, varscan2
- ATP2B2 | c.2120G>T p.R707L (on ENST00000352432; = p.R673L on NM_001683.5) | Missense Mutation (SNP) | VAF 23/24 reads (96%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.496); catalogued as COSV59505783; called by muse, mutect2, varscan2
- BANK1 | c.1849C>T p.R617* | Nonsense Mutation (SNP) | VAF 27/33 reads (82%) | catalogued as rs1560696993; called by muse, mutect2, varscan2
- BPIFC | c.368C>A p.P123Q | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.899); catalogued as COSV55915330; called by muse, mutect2, varscan2
- C12orf43 | c.508G>T p.D170Y | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56567558; called by muse, mutect2, varscan2
- CBWD1 | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 168/366 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.224); catalogued as rs1294140306, COSV58703608; called by muse, mutect2, varscan2
- CD6 | c.1876G>A p.G626R | Missense Mutation (SNP) | VAF 28/30 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1304919313; called by muse, mutect2, varscan2
- CFAP251 | c.3166G>C p.G1056R | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV56615731; called by muse, mutect2, varscan2
- CSMD3 | c.4190C>T p.T1397I (on ENST00000297405 / NM_001363185.1; = p.T1293I on NM_052900.3) | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV99837828; called by muse, mutect2, varscan2
- CUX2 | c.1971G>T p.Q657H | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99918244; called by muse, mutect2, varscan2
- CYP2A13 | c.1351C>G p.L451V | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as COSV57836510; called by muse, mutect2
- DACH1 | c.1700A>T p.E567V (on ENST00000619232 / NM_001366712.1; = p.E515V on NM_080759.6) | Missense Mutation (SNP) | VAF 19/21 reads (90%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.68); catalogued as COSV100498260; called by muse, mutect2, varscan2
- DAPK1 | c.2198C>A p.P733H | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.14); PolyPhen benign (0.259); catalogued as COSV63790101; called by muse, mutect2, varscan2
- DCAF12L2 | c.643G>T p.G215C | Missense Mutation (SNP) | VAF 38/42 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100758828, COSV63580143; called by muse, mutect2, varscan2
- DGKI | c.2357G>C p.R786P | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55944421, COSV55982858; called by muse, varscan2
- DHPS | c.147C>A p.F49L | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV52951591, COSV52951708, COSV52952106; called by muse, mutect2, varscan2
- DISP3 | c.2239G>T p.A747S | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.919); catalogued as COSV53835423; called by muse, mutect2, varscan2
- DNMBP | c.1036G>T p.A346S | Missense Mutation (SNP) | VAF 11/11 reads (100%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.026); catalogued as rs1359859318; called by muse, mutect2, varscan2
- ENPP7 | c.275G>C p.G92A | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100093535; called by muse, mutect2, varscan2
- FANK1 | c.539G>T p.S180I | Missense Mutation (SNP) | VAF 35/40 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100904789; called by muse, mutect2, varscan2
- FCRL2 | c.811G>T p.G271C | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63833440; called by muse, mutect2, varscan2
- GLG1 | c.2101C>G p.Q701E | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.173); catalogued as COSV52669333, COSV99215917; called by muse, mutect2, varscan2
- GLRA3 | c.1251G>C p.M417I | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV56862783, COSV99927594; called by muse, mutect2, varscan2
- GRM7 | c.677C>A p.S226* | Nonsense Mutation (SNP) | VAF 28/33 reads (85%) | catalogued as COSV100735523; called by muse, mutect2, varscan2
- H1-1 | c.444G>C p.K148N | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.368); catalogued as COSV55119884; called by muse, mutect2, varscan2
- HCRTR2 | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); catalogued as rs199660644, COSV63794773; called by muse, mutect2, varscan2
- HOXD3 | c.193G>T p.G65C | Missense Mutation (SNP) | VAF 31/36 reads (86%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.75); catalogued as COSV99980081; called by muse, mutect2, varscan2
- IGHA1 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.255); catalogued as rs374415541; called by muse, mutect2, varscan2
- LILRB1 | c.1234C>G p.Q412E (on ENST00000427581; = p.Q376E on NM_006669.6) | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.074); catalogued as rs1419871422, COSV100206965; called by muse, mutect2
- LRRC37A3 | c.3688G>C p.A1230P | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.554); catalogued as COSV58534839; called by muse, mutect2, varscan2
- LRRC4B | c.1356C>G p.N452K | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100975978; called by muse, mutect2, varscan2
- MAB21L2 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV58262662; called by muse, mutect2, varscan2
- MAGEB6 | c.371A>C p.Y124S | Missense Mutation (SNP) | VAF 27/31 reads (87%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143802048, COSV66872741; called by muse, mutect2, varscan2
- MROH7 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs531104510, COSV59878973; called by muse, varscan2
- MTUS2 | c.3774G>C p.K1258N (on ENST00000612955 / NM_001366650.1; = p.K237N on NM_015233.6) | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV66421047; called by muse, mutect2, varscan2
- MYCBP2 | c.8051C>T p.S2684F (on ENST00000357337; = p.S2722F on NM_015057.5) | Missense Mutation (SNP) | VAF 28/39 reads (72%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as rs1011980705; called by muse, mutect2, varscan2
- MYH13 | c.3836T>A p.M1279K | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV52840720; called by muse, mutect2, varscan2
- NIPBL | c.4561-1G>T p.X1521_splice | Splice Site (SNP) | VAF 13/41 reads (32%) | catalogued as COSV99242529; called by muse, mutect2, varscan2
- NOL12 | c.118G>T p.E40* | Nonsense Mutation (SNP) | VAF 23/52 reads (44%) | catalogued as rs376416869; called by muse, mutect2, varscan2
- NRK | c.205C>G p.R69G | Missense Mutation (SNP) | VAF 43/52 reads (83%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV54589498; called by muse, mutect2, varscan2
- NRXN3 | c.1909G>T p.V637L (on ENST00000557594 / NM_001272020.2; = p.V1061L on NM_004796.6) | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55324985; called by muse, mutect2, varscan2
- OR12D3 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs766788643, COSV101011149; called by muse, mutect2, varscan2
- OR6C65 | c.181C>T p.L61F | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.714); catalogued as COSV101110223; called by muse, mutect2, varscan2
- OR6T1 | c.382C>T p.R128* | Nonsense Mutation (SNP) | VAF 49/80 reads (61%) | catalogued as rs755409697, COSV58306666; called by muse, mutect2, varscan2
- OR8K5 | c.321C>G p.F107L | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.993); catalogued as COSV57891208, COSV57891272; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.127G>C p.E43Q (on ENST00000259318 / NM_001136562.3; = p.E274Q on NM_007203.5) | Missense Mutation (SNP) | VAF 23/27 reads (85%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV52181441; called by muse, mutect2, varscan2
- PCDH15 | c.487G>T p.G163C | Missense Mutation (SNP) | VAF 27/31 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57284054; called by muse, mutect2, varscan2
- PCSK5 | c.257C>G p.S86W | Missense Mutation (SNP) | VAF 33/38 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs771011461, COSV100949807, COSV65084209; called by muse, mutect2, varscan2
- PHF21B | c.727G>C p.E243Q | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.157); catalogued as COSV57563213; called by muse, mutect2, varscan2
- PRR15 | c.313G>T p.A105S | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV100153931; called by muse, mutect2, varscan2
- PRRT3 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.018); catalogued as rs1233031278; called by muse, mutect2, varscan2
- PRSS35 | c.585T>A p.S195R | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100864077; called by muse, mutect2, varscan2
- RALYL | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs527942610, COSV72822111, COSV72822148; called by muse, mutect2, varscan2
- RHBDF1 | c.910G>C p.G304R | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0.298); catalogued as rs769452521, COSV99244170; called by muse, mutect2, varscan2
- RYR3 | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750313484, COSV101212934, COSV66783429; called by muse, mutect2, varscan2
- SERPINA4 | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.92); PolyPhen benign (0.036); catalogued as rs539993882; called by muse, mutect2, varscan2
- SHANK2 | c.3590G>C p.G1197A | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.145); catalogued as COSV53610738; called by muse, mutect2, varscan2
- SLC17A4 | c.938C>G p.A313G | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.439); catalogued as rs374082636; called by muse, mutect2, varscan2
- SLC22A1 | c.1498G>C p.A500P | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as rs777622481; called by muse, mutect2, varscan2
- SLC6A19 | c.1735C>A p.P579T | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57250015; called by muse, mutect2, varscan2
- SMG8 | c.1817G>T p.R606L | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56287533; called by muse, mutect2, varscan2
- SMYD1 | c.294G>T p.K98N | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as rs368545680; called by muse, mutect2, varscan2
- SOCS5 | c.464G>C p.R155P | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV60603650; called by muse, mutect2, varscan2
- SOX30 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99398138; called by muse, mutect2, varscan2
- SP140L | c.760C>G p.L254V | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.835); catalogued as COSV54743347; called by muse, mutect2, varscan2
- TFF3 | c.26C>G p.P9R | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.035); catalogued as rs561102941, COSV52294099; called by muse, mutect2, varscan2
- TTN | c.9478G>A p.E3160K (on ENST00000591111; = p.E3114K on NM_003319.4) | Missense Mutation (SNP) | VAF 12/16 reads (75%) | PolyPhen probably damaging (0.994); catalogued as rs976229250; called by muse, mutect2
- TUBB8 | c.628A>G p.I210V | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs781853492; called by muse, mutect2, varscan2
- TULP1 | c.1258C>G p.R420G | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as CM135101; called by muse, mutect2, varscan2
- ZNF415 | c.28G>T p.D10Y | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99701347; called by muse, mutect2, varscan2
- ZNF528 | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV64618996; called by muse, mutect2, varscan2
- ABCB1 | c.460G>T p.A154S | Missense Mutation (SNP) | VAF 187/219 reads (85%) | SIFT tolerated (0.67); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- ABCC9 | c.2427C>A p.G809= | Splice Region (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2, varscan2
- ACSM2B | c.1194G>T p.K398N | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ADAM18 | c.1042G>C p.A348P | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADRA1A | c.1301G>T p.C434F | Missense Mutation (SNP) | VAF 35/42 reads (83%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- AGBL1 | c.637G>T p.G213C | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- AMBRA1 | c.3322G>T p.A1108S (on ENST00000458649 / NM_001367468.1; = p.A1018S on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ATP8B4 | c.3016G>T p.V1006F | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ATXN10 | c.1013G>C p.R338P | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- C12orf50 | c.316C>A p.P106T | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- CACNG4 | c.341_348dup p.L117Afs*90 | Frame Shift Ins (INS) | VAF 11/61 reads (18%) | called by mutect2, varscan2
- CBFA2T3 | c.1378del p.A460Pfs*8 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- CCDC87 | c.2404G>T p.G802W | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEP85L | c.2283G>T p.E761D | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- CHMP4C | c.495G>T p.M165I | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- CLGN | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- COMMD1 | c.535G>C p.E179Q | Missense Mutation (SNP) | VAF 62/103 reads (60%) | SIFT tolerated (0.43); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- CPXCR1 | c.292A>G p.R98G | Missense Mutation (SNP) | VAF 22/23 reads (96%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- CRX | c.589C>A p.P197T | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.39); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- CSF3R | c.923G>C p.R308P | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DCDC1 | c.2905G>T p.E969* (on ENST00000597505 / NM_001367979.1; = p.E76* on NM_020869.3) | Nonsense Mutation (SNP) | VAF 16/23 reads (70%) | called by muse, mutect2, varscan2
- DEFB136 | c.161G>T p.C54F | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, varscan2
- DGKI | c.1238G>T p.G413V | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DMD | c.2894C>A p.P965H | Missense Mutation (SNP) | VAF 31/36 reads (86%) | SIFT tolerated (0.12); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- DOCK4 | c.3356C>T p.S1119L | Missense Mutation (SNP) | VAF 302/318 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- DPP6 | c.497G>T p.R166I (on ENST00000377770 / NM_001364500.2; = p.R104I on NM_001936.5) | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DVL3 | c.248G>A p.G83D | Missense Mutation (SNP) | VAF 64/77 reads (83%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ELAPOR2 | c.1414G>A p.G472R (on ENST00000450689 / NM_001142749.3; = p.G305R on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- EXD1 | c.1172A>C p.N391T | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- EXOC6B | c.2117G>T p.C706F | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FAM71D | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- FBN3 | c.5367C>A p.C1789* | Nonsense Mutation (SNP) | VAF 9/16 reads (56%) | called by muse, mutect2, varscan2
- FCRL3 | c.1789G>C p.A597P | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- FCRL3 | c.1009C>A p.R337S | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- FLG | c.6566C>A p.A2189E | Missense Mutation (SNP) | VAF 83/253 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FMN1 | c.2426G>A p.R809K (on ENST00000616417 / NM_001277313.2; = p.R586K on NM_001103184.4) | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- FREM2 | c.7832C>G p.P2611R | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- GRM7 | c.1172C>A p.T391K | Missense Mutation (SNP) | VAF 30/35 reads (86%) | SIFT deleterious (0.05); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- GRM8 | c.94C>T p.H32Y | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRTP1 | c.221G>T p.R74L | Missense Mutation (SNP) | VAF 20/22 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HIP1 | c.1642G>T p.E548* | Nonsense Mutation (SNP) | VAF 12/18 reads (67%) | called by muse, mutect2, varscan2
- HMCN1 | c.15328G>A p.E5110K | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HYDIN | c.12986G>T p.G4329V | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKV2-24 | c.198_199del p.Q67Afs*8 | Frame Shift Del (DEL) | VAF 34/80 reads (43%) | called by muse*, mutect2, varscan2*
- IGLV2-18 | c.158G>T p.R53L | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, mutect2
- IL1RAPL2 | c.1058A>C p.Y353S | Missense Mutation (SNP) | VAF 41/44 reads (93%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- IMPG1 | c.2194C>A p.P732T | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- INHBE | c.901C>T p.L301F | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- INPP5F | c.1405C>T p.Q469* | Nonsense Mutation (SNP) | VAF 21/23 reads (91%) | called by muse, mutect2, varscan2
- ITK | c.1853C>A p.S618* | Nonsense Mutation (SNP) | VAF 14/14 reads (100%) | called by muse, mutect2, varscan2
- JMJD6 | c.1096G>C p.E366Q | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- KMT5C | c.1388G>T p.*463Lext*33 | Nonstop Mutation (SNP) | VAF 8/13 reads (62%) | called by muse, varscan2
- KNDC1 | c.3175G>T p.G1059W | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- LAMA5 | c.6703G>T p.V2235L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.011); called by mutect2, varscan2
- LPCAT2 | c.1594G>C p.E532Q | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MAGI2 | c.2431G>T p.G811C | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- MCL1 | c.763A>C p.S255R | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MICAL1 | c.2322T>A p.S774R | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MKRN3 | c.942C>A p.C314* | Nonsense Mutation (SNP) | VAF 22/39 reads (56%) | called by muse, mutect2, varscan2
- MKX | c.528C>G p.H176Q | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MROH5 | c.3721C>T p.L1241F | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- MYF6 | c.696dup p.L233Tfs*37 | Frame Shift Ins (INS) | VAF 36/93 reads (39%) | called by mutect2, pindel, varscan2
- MYLK | c.3143A>G p.K1048R | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.19); PolyPhen benign (0.047); called by muse, mutect2
- NCOA3 | c.743G>T p.C248F | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NDC80 | c.952G>T p.E318* | Nonsense Mutation (SNP) | VAF 16/51 reads (31%) | called by muse, mutect2, varscan2
- NEGR1 | c.418A>C p.K140Q | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.2); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- NOTCH3 | c.4441G>T p.D1481Y | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NPAP1 | c.1101C>A p.H367Q | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- NUAK2 | c.635G>C p.S212T | Missense Mutation (SNP) | VAF 26/30 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NUCB2 | c.856G>T p.D286Y | Missense Mutation (SNP) | VAF 98/109 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OBSCN | c.8592G>T p.K2864N | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- OR2J2 | c.773G>T p.C258F | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT tolerated (0.48); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- OTOGL | c.336C>T p.I112= (on ENST00000547103; = p.I103= on NM_173591.4 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 14/28 reads (50%) | called by muse, mutect2, varscan2
- OVCH1 | c.2125G>T p.D709Y | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- PCDHB7 | c.2033C>A p.P678Q | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PCDHGC5 | c.745G>T p.V249L | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- PLCZ1 | c.90A>T p.K30N | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- PLEKHG5 | c.652G>T p.A218S (on ENST00000400915 / NM_001042663.3; = p.A181S on NM_020631.6) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PLS1 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PLSCR1 | c.613_630del p.Y205_W210del | In Frame Del (DEL) | VAF 12/92 reads (13%) | called by mutect2, pindel
- PLXND1 | c.3797G>C p.G1266A | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT tolerated (0.06); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- POLR1C | c.7G>T p.A3S | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PPP1CA | c.415G>T p.E139* | Nonsense Mutation (SNP) | VAF 19/121 reads (16%) | called by muse, mutect2, varscan2
- RHBDF1 | c.1723-1G>T p.X575_splice | Splice Site (SNP) | VAF 18/40 reads (45%) | called by muse, mutect2, varscan2
- RIBC2 | c.727G>C p.D243H | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- RIPOR2 | c.95G>T p.R32L | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- RNF17 | c.1075C>A p.P359T | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SEZ6L2 | c.211+1G>C p.X71_splice | Splice Site (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- SLCO1C1 | c.1172C>A p.A391D | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- SNX17 | c.1258G>C p.E420Q | Missense Mutation (SNP) | VAF 43/74 reads (58%) | SIFT tolerated (0.32); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- SNX20 | c.763C>G p.Q255E | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPECC1L | c.1282A>G p.T428A | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- SPTBN4 | c.2977G>T p.V993L | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SYT3 | c.935G>C p.G312A | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TBC1D16 | c.1910C>A p.T637K | Missense Mutation (SNP) | VAF 40/51 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TENM4 | c.5585G>T p.R1862L | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TMEM39A | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 26/27 reads (96%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRAPPC12 | c.1182G>T p.R394S | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- TRAV1-2 | c.162A>C p.Q54H | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRAV23DV6 | c.43C>G p.Q15E | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- TRGC2 | c.29C>G p.P10R | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRIML2 | c.188G>T p.R63M | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TRRAP | c.11536G>A p.D3846N (on ENST00000359863 / NM_001244580.1; = p.D3817N on NM_003496.3) | Missense Mutation (SNP) | VAF 13/352 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.299); called by muse, mutect2
- TTN | c.25183G>T p.E8395* (on ENST00000591111; = p.E7468* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 22/24 reads (92%) | called by muse, mutect2, varscan2
- UGGT1 | c.2324G>T p.R775L | Missense Mutation (SNP) | VAF 49/61 reads (80%) | SIFT deleterious (0); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- UGT2B15 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- UGT8 | c.844G>T p.G282C | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- UQCRC2 | c.25T>A p.S9T | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF500 | c.784G>T p.G262C | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ZNF551 | c.595A>G p.T199A | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.13); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ZNF750 | c.593C>A p.S198* | Nonsense Mutation (SNP) | VAF 13/17 reads (76%) | called by muse, mutect2, varscan2
- ZNF780A | c.595G>T p.G199W | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCC6 | c.1986C>A p.V662= | Silent (SNP) | VAF 19/52 reads (37%) | called by muse, mutect2, varscan2
- ADGRB3 | c.3291G>T p.A1097= | Silent (SNP) | VAF 34/75 reads (45%) | catalogued as COSV53238158; called by muse, mutect2, varscan2
- ARG2 | c.594G>C p.L198= | Silent (SNP) | VAF 37/84 reads (44%) | called by muse, mutect2, varscan2
- ART3 | c.792C>A p.T264= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as COSV61914047; called by muse, mutect2, varscan2
- BRF2 | c.594G>A p.E198= | Silent (SNP) | VAF 23/130 reads (18%) | called by muse, mutect2, varscan2
- BTG3 | c.15T>C p.I5= | Silent (SNP) | VAF 19/43 reads (44%) | called by muse, mutect2, varscan2
- CACNA1E | c.1257G>T p.R419= | Silent (SNP) | VAF 30/54 reads (56%) | called by muse, mutect2, varscan2
- CACNA1E | c.1647G>A p.V549= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as COSV100702130; called by muse, mutect2, varscan2
- CBFA2T3 | c.1377C>T p.S459= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs2272437, COSV51923038; called by mutect2, varscan2
- CDC42BPB | c.2013G>T p.R671= | Silent (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- CDH2 | c.2478C>A p.A826= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV52274696; called by muse, mutect2
- COG7 | c.54T>C p.N18= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs1348861782; called by muse, mutect2, varscan2
- ELMOD1 | c.543G>T p.L181= | Silent (SNP) | VAF 34/70 reads (49%) | called by muse, mutect2, varscan2
- EPB41L5 | c.1932G>A p.E644= | Silent (SNP) | VAF 16/19 reads (84%) | catalogued as rs1265207411; called by muse, mutect2, varscan2
- EPPK1 | c.265C>A p.R89= | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as rs782220071, COSV73262266; called by muse, mutect2, varscan2
- FAM81A | c.834C>A p.A278= | Silent (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- FES | c.1441C>T p.L481= | Silent (SNP) | VAF 21/53 reads (40%) | called by muse, mutect2, varscan2
- GRIN2B | c.3778C>T p.L1260= | Silent (SNP) | VAF 20/36 reads (56%) | called by muse, mutect2, varscan2
- GSE1 | c.2610C>T p.F870= | Silent (SNP) | VAF 25/49 reads (51%) | catalogued as rs1182629889; called by muse, mutect2, varscan2
- H2BC6 | c.222C>T p.I74= | Silent (SNP) | VAF 38/93 reads (41%) | catalogued as rs769608700, COSV61590933; called by muse, mutect2, varscan2
- HECTD4 | c.5592A>T p.G1864= | Silent (SNP) | VAF 16/36 reads (44%) | called by muse, mutect2, varscan2
- HYDIN | c.12252C>A p.I4084= | Silent (SNP) | VAF 11/30 reads (37%) | called by mutect2, varscan2
- IGFN1 | c.2425C>A p.R809= (on ENST00000295591 / NM_001367841.1; = p.R3266= on NM_001164586.2) | Silent (SNP) | VAF 33/40 reads (83%) | called by muse, mutect2, varscan2
- IL12RB1 | c.1878C>A p.G626= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV101651922, COSV74045659; called by muse, mutect2, varscan2
- IL1RAPL1 | c.357C>A p.V119= | Silent (SNP) | VAF 25/27 reads (93%) | called by muse, mutect2, varscan2
- ITGAD | c.2217C>G p.P739= | Silent (SNP) | VAF 20/44 reads (45%) | called by muse, mutect2, varscan2
- LCP1 | c.1182G>T p.T394= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as COSV59940524; called by muse, mutect2, varscan2
- MARVELD2 | c.732G>T p.G244= | Silent (SNP) | VAF 43/52 reads (83%) | called by muse, mutect2, varscan2
- MEOX1 | c.189A>T p.S63= | Silent (SNP) | VAF 32/61 reads (52%) | catalogued as rs367782056, COSV100233784; called by muse, mutect2, varscan2
- MTMR3 | c.1794C>T p.T598= | Silent (SNP) | VAF 15/53 reads (28%) | called by muse, mutect2, varscan2
- MYO1F | c.1842C>A p.I614= | Silent (SNP) | VAF 32/63 reads (51%) | catalogued as rs1316343661; called by muse, mutect2, varscan2
- NAA11 | c.255C>A p.G85= | Silent (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2, varscan2
- NCAPH | c.465G>T p.A155= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV99545427; called by muse, mutect2, varscan2
- NRXN1 | c.3810G>T p.L1270= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as COSV60482306, COSV60495809; called by muse, mutect2, varscan2
- OBP2A | c.366G>C p.L122= | Silent (SNP) | VAF 10/12 reads (83%) | called by muse, varscan2
- OR5T2 | c.531C>G p.P177= | Silent (SNP) | VAF 45/108 reads (42%) | called by muse, mutect2, varscan2
- PAPPA | c.1944G>T p.T648= | Silent (SNP) | VAF 15/18 reads (83%) | called by muse, mutect2, varscan2
- PAXIP1 | c.228G>A p.V76= | Silent (SNP) | VAF 9/11 reads (82%) | called by muse, mutect2, varscan2
- PCDHA2 | c.2199G>A p.A733= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as COSV65367530; called by muse, mutect2, varscan2
- PCDHA9 | c.1689G>C p.P563= | Silent (SNP) | VAF 48/89 reads (54%) | called by muse, mutect2, varscan2
- PCDHAC2 | c.900G>T p.T300= | Silent (SNP) | VAF 13/22 reads (59%) | called by muse, mutect2, varscan2
- PCDHB13 | c.492C>A p.G164= | Silent (SNP) | VAF 23/53 reads (43%) | called by muse, mutect2, varscan2
- PCDHB6 | c.2133G>T p.L711= | Silent (SNP) | VAF 48/128 reads (38%) | called by muse, mutect2, varscan2
- PDGFC | c.468C>T p.F156= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as rs1321994981; called by muse, mutect2, varscan2
- PIK3R6 | c.753G>A p.L251= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV100266742; called by muse, mutect2, varscan2
- POGLUT2 | c.882G>T p.T294= | Silent (SNP) | VAF 14/17 reads (82%) | catalogued as rs1267596670, COSV65682740; called by muse, mutect2, varscan2
- POLE | c.6666G>T p.L2222= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as COSV100265536, COSV57687369; called by muse, mutect2, varscan2
- PRKCB | c.924C>A p.A308= | Silent (SNP) | VAF 31/80 reads (39%) | called by muse, mutect2, varscan2
- PRUNE2 | c.8322C>G p.G2774= | Silent (SNP) | VAF 12/12 reads (100%) | catalogued as COSV56314168; called by muse, mutect2, varscan2
- PTGDR2 | c.507C>T p.F169= | Silent (SNP) | VAF 15/19 reads (79%) | catalogued as rs1189197399; called by muse, mutect2, varscan2
- RADIL | c.1077G>T p.A359= | Silent (SNP) | VAF 10/23 reads (43%) | called by muse, mutect2, varscan2
- RASGRP3 | c.1170C>A p.T390= (on ENST00000402538 / NM_001349975.2; = p.T389= on NM_015376.2 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 19/40 reads (48%) | called by muse, mutect2, varscan2
- RFTN1 | c.552C>A p.T184= | Silent (SNP) | VAF 11/12 reads (92%) | catalogued as COSV100489515; called by muse, mutect2, varscan2
- SLC6A9 | c.279G>A p.K93= (on ENST00000360584 / NM_201649.4; = p.K39= on NM_006934.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- SMARCAL1 | c.600G>A p.S200= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as rs530505647; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMARCD1 | c.1488C>T p.Y496= | Silent (SNP) | VAF 31/76 reads (41%) | called by muse, mutect2, varscan2
- SPAG17 | c.2994C>A p.V998= | Silent (SNP) | VAF 43/100 reads (43%) | called by muse, mutect2, varscan2
- TANGO6 | c.2721C>T p.D907= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as rs759364664; called by muse, mutect2, varscan2
- TBX22 | c.771C>A p.T257= | Silent (SNP) | VAF 17/18 reads (94%) | catalogued as COSV64788580; called by muse, mutect2, varscan2
- TENM4 | c.5586G>T p.R1862= | Silent (SNP) | VAF 28/116 reads (24%) | called by muse, mutect2, varscan2
- TMPRSS5 | c.210G>T p.L70= | Silent (SNP) | VAF 28/40 reads (70%) | called by muse, mutect2, varscan2
- TMPRSS6 | c.756G>T p.L252= | Silent (SNP) | VAF 36/73 reads (49%) | called by muse, mutect2, varscan2
- TSPEAR | c.609G>T p.R203= | Silent (SNP) | VAF 18/54 reads (33%) | called by muse, mutect2, varscan2
- TULP4 | c.2091G>A p.S697= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as rs750680160, COSV100893356; called by muse, mutect2, varscan2
- UGGT1 | c.891G>T p.L297= | Silent (SNP) | VAF 17/20 reads (85%) | called by muse, mutect2, varscan2
- UNC13B | c.3774G>T p.A1258= | Silent (SNP) | VAF 16/20 reads (80%) | catalogued as COSV65931330; called by muse, mutect2, varscan2
- USP43 | c.1863G>A p.Q621= | Silent (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2, varscan2
- XKR4 | c.1533C>G p.A511= | Silent (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
- ZNF425 | c.2208G>T p.A736= | Silent (SNP) | VAF 18/23 reads (78%) | catalogued as COSV65203036; called by muse, mutect2, varscan2
- ZNF445 | c.792G>T p.L264= | Silent (SNP) | VAF 36/46 reads (78%) | called by muse, mutect2, varscan2
- AC244258.1 | n.291C>A | RNA (SNP) | VAF 13/32 reads (41%) | catalogued as rs761743105; called by muse, mutect2, varscan2
- CCT5 | c.-1C>T | 5'UTR (SNP) | VAF 50/79 reads (63%) | catalogued as rs1408639316; called by muse, mutect2, varscan2
- JAKMIP1 | chr4:6048882 C>A | 3'Flank (SNP) | VAF 23/27 reads (85%) | catalogued as COSV51530401; called by muse, mutect2, varscan2
- JAKMIP1 | chr4:6048883 C>A | 3'Flank (SNP) | VAF 22/26 reads (85%) | called by muse, mutect2, varscan2
- KIR3DX1 | n.1047G>T | RNA (SNP) | VAF 21/48 reads (44%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85740C>T | Intron (SNP) | VAF 53/104 reads (51%) | catalogued as rs1467257957, COSV72279319, COSV72284299; called by muse, mutect2, varscan2
- MIR770 | n.87G>T | RNA (SNP) | VAF 12/30 reads (40%) | called by muse, mutect2, varscan2
- REXO1L1P | n.55G>T | RNA (SNP) | VAF 19/130 reads (15%) | called by muse, mutect2, varscan2
- SNORD115-26 | n.37A>C | RNA (SNP) | VAF 35/80 reads (44%) | called by muse, mutect2, varscan2
- SV2C | c.581-21226dup | Intron (INS) | VAF 31/49 reads (63%) | called by mutect2, pindel, varscan2
- ZNF578 | chr19:52451214 G>T | 5'Flank (SNP) | VAF 32/50 reads (64%) | called by muse, mutect2, varscan2
